TCGA case TCGA-97-7552 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b110eb4-a01d-4c50-ba18-77da4dedd549

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (3)
1. Bronchio-alveolar carcinoma, mucinous (the primary disease): ICD-O-3 morphology code: 8253/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 70.0 years (25,578 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 72.2 years (26,376 days); Days to diagnosis: 798 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.2 years (26,376 days); Days to diagnosis: 798 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 798 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,476 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,932 days (5.3 years); Disease response: Tumor Free.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 82; FEV1 before bronchodilator (% of reference): 81.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40; Tobacco smoking quit year: 1985.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-7552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-97-7552-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 60; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 25.
  Slide TCGA-97-7552-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 50; Percent normal cells: 35; Percent necrosis: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5.
- Sample TCGA-97-7552-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-97-7552-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Bronchioloalveolar Carcinoma Mucinous; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; Pulmonary function test indicator: Yes.
- Follow-up form 1: New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2, New neoplasm event types: New tumor event type: New Primary Tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,932 days; disease-specific survival: no event (censored), 1,932 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 798 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-7552-01A-11D-2035-01): tumor purity 0.18, ploidy 1.95, whole-genome doublings 0.
